Somatic mutation profile of tumor specimen C3N-02012-01 (aliquot CPT0115470009) from CPTAC case C3N-02012, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.2 years (25,277 days).
Specimen C3N-02012-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32e8b619-d48f-4862-a1fc-d9f7724ff0e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02012-31 (Blood Derived Normal), aliquot CPT0116390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc92dce-f749-4593-ae2c-f7658dbaa039

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Nonsense Mutation 4, Intron 4, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 126/416 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3199G>T p.D1067Y | Missense Mutation (SNP) | VAF 94/293 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56684065, COSV56687870; called by muse, mutect2, varscan2
- AMPD1 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 127/430 reads (30%) | catalogued as rs377185948, COSV100815143; called by muse, mutect2, varscan2
- APAF1 | c.1823G>A p.R608H (on ENST00000551964 / NM_181861.2; = p.R597H on NM_001160.3) | Missense Mutation (SNP) | VAF 98/372 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as rs554955493, COSV59669271; called by muse, mutect2, varscan2
- ARID1A | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 60/199 reads (30%) | catalogued as COSV61373914; called by muse, mutect2, varscan2
- CIT | c.5443G>A p.G1815R | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774793121; called by muse, mutect2, varscan2
- CTCF | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50475306, COSV50509468; called by muse, mutect2, varscan2
- GRID2IP | c.3610G>A p.G1204R | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.066); catalogued as rs574381220; called by muse, mutect2, varscan2
- HK1 | c.781T>A p.W261R | Missense Mutation (SNP) | VAF 474/956 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100065518; called by muse, mutect2, varscan2
- INPPL1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 138/219 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773085707, COSV53357373; called by muse, mutect2, varscan2
- KLHL33 | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs543538009, COSV60725805; called by muse, mutect2, varscan2
- PRPF8 | c.4780T>C p.C1594R | Missense Mutation (SNP) | VAF 142/479 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100517817; called by muse, mutect2, varscan2
- PSMB5 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 36/838 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs145689628; called by muse, mutect2
- RELCH | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1474871282; called by muse, mutect2
- TMEM151A | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as rs1023330006, COSV59173631; called by muse, mutect2, varscan2
- TUBB8 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 388/1110 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as rs147863681, COSV59116206; called by muse, varscan2
- USP28 | c.622-1G>A p.X208_splice | Splice Site (SNP) | VAF 35/64 reads (55%) | catalogued as COSV50190847; called by muse, mutect2, varscan2
- USP34 | c.5986G>A p.E1996K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs188433515, COSV101276761, COSV68406980; called by muse, mutect2, varscan2
- ZC3H13 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 87/326 reads (27%) | catalogued as COSV54447348; called by muse, mutect2, varscan2
- ACVR2A | c.708_709del p.Y236* | Frame Shift Del (DEL) | VAF 67/227 reads (30%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.17088_17102del p.C5696_P5701delins* | Nonsense Mutation (DEL) | VAF 34/172 reads (20%) | called by mutect2, pindel, varscan2
- CELSR1 | c.2890dup p.Y964Lfs*17 | Frame Shift Ins (INS) | VAF 61/200 reads (31%) | called by mutect2, pindel, varscan2
- GJA3 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GRIP2 | c.1475C>A p.P492Q (on ENST00000619221; = p.P395Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2
- KIF3B | c.1748+3_1748+6del p.X583_splice | Splice Site (DEL) | VAF 50/182 reads (27%) | called by pindel, varscan2
- P2RX2 | c.1429A>C p.T477P (on ENST00000343948 / NM_170683.4; = p.T379P on NM_012226.5) | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PCDHB7 | c.1081C>G p.P361A | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRKRA | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 97/400 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTEN | c.940del p.E314Nfs*3 | Frame Shift Del (DEL) | VAF 231/400 reads (58%) | called by mutect2, pindel, varscan2
- RIN2 | c.1648A>T p.S550C (on ENST00000255006 / NM_001242581.1; = p.S501C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/690 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- TNMD | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.297); called by muse, varscan2
- TRIM64B | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 113/371 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); called by mutect2, varscan2
- TTC16 | c.2556G>T p.W852C | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- UFL1 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- YY1 | c.690dup p.D231Rfs*3 | Frame Shift Ins (INS) | VAF 52/186 reads (28%) | called by mutect2, varscan2
- BCL11B | c.1509C>T p.S503= (on ENST00000357195 / NM_001282237.2; = p.S432= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/382 reads (29%) | catalogued as rs995562955; called by muse, varscan2
- KCNA5 | c.1407C>T p.D469= | Silent (SNP) | VAF 157/522 reads (30%) | catalogued as rs768740011, CM1212184, COSV52907745, COSV52909252; called by muse, mutect2, varscan2
- KCNS3 | c.624G>A p.S208= | Silent (SNP) | VAF 60/224 reads (27%) | catalogued as rs140824188; called by muse, mutect2, varscan2
- LGI3 | c.1242G>A p.Q414= | Silent (SNP) | VAF 183/531 reads (34%) | catalogued as COSV60444325; called by muse, mutect2, varscan2
- LSM10 | c.369G>A p.K123= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs762361610; called by muse, mutect2
- OTOP1 | c.453A>G p.K151= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV56397985; called by muse, mutect2, varscan2
- PRR23B | c.465C>T p.Y155= | Silent (SNP) | VAF 69/581 reads (12%) | catalogued as rs1288923649, COSV100271924, COSV61494977; called by muse, mutect2, varscan2
- SLCO2A1 | c.1347G>T p.S449= | Silent (SNP) | VAF 72/245 reads (29%) | catalogued as rs373457618, COSV100189068, COSV60490407; called by muse, mutect2, varscan2
- SPRED1 | c.669A>G p.L223= | Silent (SNP) | VAF 88/346 reads (25%) | catalogued as rs774530752; ClinVar: likely benign; called by muse, mutect2, varscan2
- YBX2 | c.1020C>T p.G340= | Silent (SNP) | VAF 77/195 reads (39%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.377G>T | RNA (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- CNGA1 | c.-15+10373C>T | Intron (SNP) | VAF 37/119 reads (31%) | catalogued as rs748624136; called by muse, mutect2, varscan2
- RGS12 | c.1882-422C>T | Intron (SNP) | VAF 14/111 reads (13%) | catalogued as rs1165533206; called by muse, mutect2, varscan2
- SUGP2 | c.3128+105T>C | Intron (SNP) | VAF 81/223 reads (36%) | called by muse, mutect2, varscan2
- TMOD3 | c.*30T>G | 3'UTR (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- USP53 | chr4:119212423 G>C | 5'Flank (SNP) | VAF 91/335 reads (27%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+44503C>T | Intron (SNP) | VAF 19/82 reads (23%) | catalogued as rs762845309; called by muse, varscan2
